Somatic mutation profile of tumor specimen TCGA-BP-5189-01A (aliquot TCGA-BP-5189-01A-02D-1429-08) from TCGA case TCGA-BP-5189, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 60.7 years (22,156 days).
Specimen TCGA-BP-5189-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64116eee-6256-4a03-b314-c03d3f0ba023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5189-11A (Solid Tissue Normal), aliquot TCGA-BP-5189-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d5796be-2035-4d92-a5ef-e37c129f33e6

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 8, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64604671, COSV64606956; called by muse, mutect2
- AKAP9 | c.11600C>T p.P3867L (on ENST00000359028; = p.P3843L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV50154510; called by muse, mutect2, varscan2
- ANKRD34B | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.41); catalogued as COSV58614615; called by muse, mutect2, varscan2
- ATP1A2 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918618, CM072871, COSV63406206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV60514075; called by muse, mutect2, varscan2
- CFAP58 | c.2498A>T p.E833V | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV63836678; called by muse, mutect2, varscan2
- CLK1 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58436338; called by muse, mutect2, varscan2
- CYP11B2 | c.1146G>T p.L382F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV59998075; called by muse, mutect2, varscan2
- EIF2B2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 106/396 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721516; called by muse, mutect2, varscan2
- EPHA5 | c.3077del p.M1026Rfs*6 | Frame Shift Del (DEL) | VAF 60/236 reads (25%) | catalogued as COSV56663437; called by mutect2, pindel, varscan2
- FHOD1 | c.2579T>G p.L860R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50771724; called by muse, mutect2, varscan2
- GBA3 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV72438815; called by muse, varscan2
- HSH2D | c.235C>G p.H79D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53740261; called by muse, mutect2
- KDM5C | c.2962del p.H988Tfs*18 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as COSV64770956; called by mutect2, pindel, varscan2
- LOXL1 | c.1506G>A p.Q502= | Splice Region (SNP) | VAF 35/158 reads (22%) | catalogued as COSV56096488; called by muse, mutect2, varscan2
- MYH4 | c.4658C>T p.A1553V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV55127316; called by muse, mutect2, varscan2
- NAT8 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as COSV55543199; called by muse, mutect2, varscan2
- OGA | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 16/485 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63383602; called by muse, mutect2
- PARP16 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV56036758; called by muse, mutect2, varscan2
- PBRM1 | c.4249T>G p.W1417G (on ENST00000296302 / NM_001366071.2; = p.W1365G on NM_018313.5) | Missense Mutation (SNP) | VAF 120/457 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56307848; called by muse, varscan2
- PLEKHA7 | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.449); catalogued as COSV63047402, COSV63051626; called by muse, mutect2, varscan2
- PLEKHA7 | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV63051631; called by muse, mutect2, varscan2
- PTPRH | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV54750718, COSV99671478; called by muse, mutect2, varscan2
- RALGAPA1 | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV51898611; called by muse, mutect2, varscan2
- RGPD1 | c.4069C>G p.Q1357E (on ENST00000409776; = p.Q1365E on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/633 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as COSV101233703; called by muse, mutect2, varscan2
- RIPOR1 | c.3057C>G p.F1019L (on ENST00000379312 / NM_001193522.2; = p.F1015L on NM_024519.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50274903; called by muse, mutect2, varscan2
- SASH1 | c.1576G>C p.V526L | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66566528; called by muse, mutect2, varscan2
- SCAMP2 | c.535T>G p.S179A | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV51513551; called by muse, mutect2, varscan2
- SEC14L1 | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs751760592, COSV66725839; called by muse, mutect2, varscan2
- SLITRK4 | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV62026372; called by muse, mutect2
- SORT1 | c.886T>C p.F296L | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV56668518, COSV56670637; called by muse, mutect2, varscan2
- STAT4 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61832687; called by muse, mutect2, varscan2
- ULK1 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs752880506, COSV58856193; called by muse, mutect2, varscan2
- ZNF212 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60026329; called by muse, mutect2, varscan2
- ZNF93 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1250230591, COSV59374990, COSV59379183; called by muse, mutect2, varscan2
- ATP6V0B | c.348+1del | Frame Shift Del (DEL) | VAF 42/182 reads (23%) | called by mutect2, pindel, varscan2
- LRRTM1 | c.631_637del p.L211Sfs*12 | Frame Shift Del (DEL) | VAF 22/198 reads (11%) | called by mutect2, pindel
- LYST | c.2779del p.S927Lfs*11 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4242del p.T1415Qfs*66 (on ENST00000296302 / NM_001366071.2; = p.T1363Qfs*17 on NM_018313.5) | Frame Shift Del (DEL) | VAF 95/458 reads (21%) | called by pindel, varscan2
- SIPA1L1 | c.1879del p.E627Rfs*75 | Frame Shift Del (DEL) | VAF 37/250 reads (15%) | called by mutect2, pindel, varscan2
- TMOD4 | c.956_957del p.F319Yfs*18 | Frame Shift Del (DEL) | VAF 51/300 reads (17%) | called by mutect2, pindel, varscan2
- UBA5 | c.722_723insTTGA p.E241Dfs*2 | Frame Shift Ins (INS) | VAF 34/145 reads (23%) | called by mutect2, pindel, varscan2
- COLEC10 | c.636T>C p.N212= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV60523065; called by muse, mutect2, varscan2
- CTSB | c.876C>A p.P292= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV61540765; called by muse, mutect2, varscan2
- FTL | c.243C>T p.D81= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1297588792, COSV53171955; called by muse, mutect2, varscan2
- GTPBP8 | c.702A>G p.G234= | Silent (SNP) | VAF 7/178 reads (4%) | catalogued as rs1303680195, COSV55607702; called by muse, mutect2
- MLYCD | c.546G>T p.L182= | Silent (SNP) | VAF 60/296 reads (20%) | catalogued as COSV52306907; called by muse, mutect2, varscan2
- OTUD7B | c.1152T>C p.Y384= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV64917950; called by muse, mutect2, varscan2
- ROR1 | c.1887A>G p.V629= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as COSV64293818; called by muse, mutect2, varscan2
- TNC | c.1356C>T p.G452= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as rs773390417, COSV60791177; called by muse, mutect2, varscan2
- UBLCP1 | c.144C>G p.L48= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as COSV57144014; called by muse, mutect2, varscan2
